Somatic mutation profile of tumor specimen MP2PRT-PAPXRL-TMP1-A (aliquot MP2PRT-PAPXRL-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPXRL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (654 days).
Specimen MP2PRT-PAPXRL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c0d052c-c40a-4d44-a0e4-779a98f1a5a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPXRL-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPXRL-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddd9b8ce-7406-45d5-bdf1-e84e24149da0

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, In Frame Del 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 122/297 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDS1 | c.520_522del p.E174del | In Frame Del (DEL) | VAF 24/123 reads (20%) | catalogued as rs1277849502; called by pindel, varscan2
- HSPA12A | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 165/588 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs374696720; called by muse, mutect2, varscan2
- NSD2 | c.3532A>G p.N1178D | Missense Mutation (SNP) | VAF 125/399 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56396472; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- CASKIN1 | c.1311G>A p.P437= | Silent (SNP) | VAF 101/224 reads (45%) | catalogued as rs377070967; called by muse, mutect2, varscan2
- ANKRD13D | c.*293G>A | 3'UTR (SNP) | VAF 127/312 reads (41%) | catalogued as rs763213094; called by muse, mutect2, varscan2
